Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7854, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7854-01A (Primary Tumor).

Pathology Report for Subject [REDACTED]

Addendum Discussion:

Only a rare MIB-1 positive cell is present, consistent with the low grade histologic features. The case is reviewed with [REDACTED] who in addition to the astrocytic proliferation, notes disorganization of neurons with some atypia, as well as neurons and white matter, consistent with a background of cortical dysplasia.

Addendum Diagnosis:

Well-differentiated Astrocytoma, grade II in background of cortical dysplasia.

Microscopic Description:

Sections demonstrate a mildly to moderately hypercellular glial neoplasm that diffusely infiltrates white matter as well as gray matter. In the latter, focal perineuronal satellitosis is seen. The tumor predominantly resembles gemistocytes, although some fibrillary astrocytes are seen. Although the nuclei tend to be round to oval, perinuclear halos or other definite indications of oligodendroglioma differentiation are not seen. Atypia is mild to moderate. No mitoses are seen in 50 high power fields or on lower power scanning.

Source: NCI Genomic Data Commons file 3fc5c53b-dab4-4aa0-ba7f-321def207e3e (TCGA-HT-7854.ABFF42E8-3D5D-438C-91A8-6DDCA2225169.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).